Gene-level copy-number profile of tumor specimen ALCH-B3E7-TTP1-A from ALCHEMIST case ALCH-B3E7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,765 days).
Specimen ALCH-B3E7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da91fcff-e0c7-4106-b741-b6b131c0496a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3E7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/fbe357e1-bc15-4fbf-99d4-a1fe1e19f442

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 6,965; copy number 2: 47,357; copy number 3: 2,601; copy number 4: 694; copy number 5: 772; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,699,456–143,729,570, 3 genes: RNVU1-17, RNVU1-23, RNVU1-18.
- chr1:143,929,994–143,930,382, 1 gene (within-gene range 0–1): RPL22P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 773 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,324,756–1,328,896, 1 gene, copy number 7: CPTP.
- chr3:153,384,934–198,123,232, 772 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
